Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A950, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A950-01A (Primary Tumor).

ICD O-3

Carcinoma, squamous cell NOS
8070/3

Site: Cervix NOS
C53.9

JW 3/12/14

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix:

Poorly differentiated squamous cell carcinoma
Foci of vascular invasion present.

MDA Discrepancy		☒
For Malignancy History		☒

Source: NCI Genomic Data Commons file 3b2e797e-144e-4e57-97f3-ffab00422609 (TCGA-VS-A950.F095B0C9-4855-495D-89C9-B303D7756BFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).